Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7053, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7053-01A (Primary Tumor).

[page 1 of 3]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

1: SP: Kidney, right, partial nephrectomy

2: SP: Kidney, Deep surgical margin #2.

DIAGNOSIS:

1. SP: Kidney, right, partial nephrectomy(fs)(am):

Tumor Type:

Renal cell carcinoma - Unclassified type

The tumor has papillary, tubular, and solid features. High grade

Tumor Size:

Greatest diameter is 1.6 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3 Tumor extends into major veins or invades the adrenal gland or perinephric tissues, but not beyond fascia

Comment: While this tumor does not fit into one of our well described entities, I favor it being of distal nephron origin.

2. "Deep surgical margin#2", excision:

Benign renal parenchyma. No tumor identified.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

Special Studies:

Result	Special Stain	Comment
	CA-1X	
	NEG CONT	
	IMM RECUT	
	RECUT	
	RECUT	
	RECUT	
	CK7	
	RACEMASE	
	MIB-1 (Ki-67)	

Gross Description:

1). The specimen is received in formalin and is labeled "right renal tumor". It consists of a 2.8 x 2.8 x 2.5 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the margin at stitch pink-yellow. The specimen is serially sectioned to reveal white yellow mass measuring 1.6 X 1.5 X 1.1 cm. The tumor from the resection margin (with stitch, yellow ink) is 0.3 cm and within 0.1 cm to the closest the black inked margin. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

2). The specimen is received in formalin, labeled "Deep surgical margin number two" and consists of a 0.7 x 0.6 x 0.3 cm fragment of tan soft tissue. Entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Kidney, right, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	m	1
2	rs	2
1	t	1

Part 2: SP: Kidney, Deep surgical margin #2, excision

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: MARGIN AT STITCH IS BENIGN. CARCINOMA, NOT CLEAR CELL.

[page 3 of 3]
PERMANENT DIAGNOSIS

Source: NCI Genomic Data Commons file 024ea4e3-9b76-407f-81e1-14b2192bdf51 (TCGA-BQ-7053.3661260B-AF10-4BC7-BB15-C364DC84F15B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).